TCGA case TCGA-AK-3426 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c5265ca6-2cb5-406d-a635-c4c783561107

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 37 years; Vital status: Dead; Days to death: 885 days (2.4 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 37.7 years (13,770 days); Year of diagnosis: 2004; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 10.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 425 days (1.2 years); Days to treatment end: 445 days (1.2 years); Treatment dose: 3,750 cGy; Course number: 1; Number of fractions: 15; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Initial disease status: Recurrent Disease; Days to treatment start: 465 days (1.3 years); Days to treatment end: 522 days (1.4 years); Route of administration: Subcutaneous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 38.4 years (14,026 days); Days to diagnosis: 256 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 256 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 885 days (2.4 years); Disease response: With Tumor.
- Karnofsky performance status: 0.

Molecular and laboratory tests
- Hemoglobin: Low.
- Leukocytes: Normal.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AK-3426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-AK-3426-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-AK-3426-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-AK-3426-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 10.
- Sample TCGA-AK-3426-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AK-3426-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 2.
- Drug treatment: Regimen number: 1; Therapy regimen: Recurrence.
- Drug treatment, Route of administrations: Route of administration: SC.
- Follow-up form: New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 885 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 885 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 256 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AK-3426-01A-02D-1322-01): tumor purity 0.3, ploidy 1.75, whole-genome doublings 0.
